Gene-level copy-number profile of tumor specimen TCGA-BA-6872-01A from TCGA case TCGA-BA-6872, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; Tumor grade: G2; Age at diagnosis: 47.4 years (17,296 days).
Specimen TCGA-BA-6872-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.b2cb4d32-a05a-4eea-b6b1-c401d6d8747a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BA-6872-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ad5f80fe-fc9d-4d0d-ad68-e2945826aac8

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 869; copy number 2: 692; copy number 3: 10,701; copy number 4: 25,525; copy number 5: 11,376; copy number 6: 8,689; copy number 7: 1,086; copy number 8: 280; copy number 9: 58; copy number 10: 42; copy number 11: 23; copy number 12: 147; copy number 13: 30; copy number 14: 121; copy number 16: 43; copy number 20: 19; copy number 22: 49; copy number 26: 2; copy number 28: 36; copy number 30: 6; copy number 37: 2; copy number 40: 1; copy number 47: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BA-6872-01A-11D-1869-01): tumor purity 0.58, ploidy 3.18, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 592 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:166,403,573–167,259,753, 5 genes, copy number 10: SCN7A, AC074101.1, XIRP2, AC092601.1, XIRP2-AS1.
- chr2:172,137,345–172,370,401, 1 gene, copy number 9 (within-gene range 6–9): AC104088.1.
- chr2:172,323,260–177,618,742, 124 genes, copy number 9–16 (broad region; genes not listed).
- chr2:177,653,419–177,723,289, 1 gene, copy number 14: PDE11A-AS1.
- chr5:42,756,818–43,192,021, 20 genes, copy number 10–37 (within-gene range 6–37): CCDC152, SELENOP, AC008945.1, AC008945.2, PPIAP77, PRELID3BP4, PRELID3BP5, PRELID3BP6, PRELID3BP7, AC008875.3, AC008875.2, AC008875.1, AC025171.1, AC025171.3, AC025171.5, ANXA2R, AC025171.2, AC025171.4, ZNF131, AC106800.3.
- chr7:46,476,457–48,711,582, 25 genes, copy number 11–26: AC004869.2, AC004869.1, HMGN1P19, AC011294.1, EPS15P1, AC004870.4, AC004870.2, AC004870.3, MRPL42P4, AC004870.1, AC087175.1, TNS3, LINC01447, C7orf65, PKD1L1, LINC00525, C7orf69, AC069282.1, HUS1, SUN3, C7orf57, UPP1, ABCA13, AC091770.1, LINC02838.
- chr7:53,862,233–55,862,755, 43 genes, copy number 10–30: HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3.
- chr9:33,921,693–37,384,434, 147 genes, copy number 12 (broad region; genes not listed).
- chr11:30,773,913–30,850,559, 1 gene, copy number 40: AL122014.1.
- chr11:32,112,049–36,510,537, 92 genes, copy number 10–20 (broad region; genes not listed).
- chr11:67,965,873–72,139,892, 133 genes, copy number 9–47 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
